Somatic mutation profile of tumor specimen TCGA-BR-7707-01A (aliquot TCGA-BR-7707-01A-11D-2053-08) from TCGA case TCGA-BR-7707, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 69.3 years (25,325 days).
Specimen TCGA-BR-7707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50bd77a7-3a6c-431b-a39b-4b2b32a33a02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7707-10A (Blood Derived Normal), aliquot TCGA-BR-7707-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b867037-8d4e-417f-979c-e892c061b51d

The open-access MAF lists 1,488 somatic variants for this specimen: 1,128 protein-altering or splice-affecting, 334 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 782, Silent 334, Frame Shift Del 220, Frame Shift Ins 47, Nonsense Mutation 36, Splice Site 20, Splice Region 14, In Frame Del 9, Intron 9, RNA 7, 3'UTR 4, 5'UTR 3.

Variants (750 of 1,488; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.822); catalogued as rs281875333, CM122511, COSV59317670; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD11 | c.2412del p.E805Kfs*58 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs886039902; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- B2M | c.67+1G>A p.X23_splice | Splice Site (SNP) | VAF 72/114 reads (63%) | hotspot (GDC flag); catalogued as CS1511368, COSV62562857; called by muse, mutect2, varscan2
- BBS10 | c.235dup p.T79Nfs*17 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | catalogued as rs760693838; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA2 | c.5073del p.K1691Nfs*15 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | catalogued as rs80359479; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- GBA | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs1264734195, CM121739, COSV59169295; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- INPPL1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 8/101 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53353022, COSV99995692; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MKRN3 | c.482del p.P161Rfs*10 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, pindel
- MYH7 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs730880868, CM032602, COSV62517652; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- POMT1 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs119462987, CM061917; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTPRS | c.4474C>T p.R1492W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369295620; called by muse, mutect2, varscan2
- SLC16A1 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs606231310, CM1411337, COSV63708941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.393_395del p.N131del | In Frame Del (DEL) | VAF 10/58 reads (17%) | hotspot (GDC flag); catalogued as rs879254214; called by pindel, varscan2
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 96/402 reads (24%) | catalogued as rs751284215; called by mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 30/95 reads (32%) | catalogued as rs771808127, COSV55113098; called by mutect2, varscan2
- ABCA9 | c.4141C>T p.Q1381* | Nonsense Mutation (SNP) | VAF 40/136 reads (29%) | catalogued as COSV60622449, COSV60629133; called by muse, mutect2, varscan2
- ABCC1 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV60682720; called by muse, mutect2, varscan2
- ABCC11 | c.250del p.Q84Sfs*21 | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | catalogued as rs1567286335; called by mutect2, pindel, varscan2
- ABCC2 | c.3121G>T p.A1041S | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0.05); catalogued as COSV64985305; called by muse, mutect2
- ABCD1 | c.1730A>G p.E577G | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.777); catalogued as COSV54383945; called by muse, mutect2
- ACAA2 | c.977A>G p.Q326R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53270288; called by muse, varscan2
- ACE2 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV53024157; called by muse, mutect2
- ACP5 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs374180791; called by mutect2, varscan2
- ACRV1 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.236); catalogued as COSV59754691; called by muse, mutect2, varscan2
- ACTL9 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs782060616, COSV61005266; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 43/98 reads (44%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM11 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52345223; called by muse, mutect2, varscan2
- ADAM19 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.454); catalogued as rs199716249, COSV57426292; called by muse, mutect2, varscan2
- ADAM7 | c.1442C>A p.P481H | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs890070716, COSV51537229, COSV51541037; called by muse, mutect2, varscan2
- ADAMTS1 | c.2779G>A p.G927S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53169323; called by muse, mutect2
- ADAMTS13 | c.3127G>A p.D1043N | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.536); catalogued as rs370081995, COSV63021678; called by muse, mutect2, varscan2
- ADCY4 | c.2430T>C p.N810= | Splice Region (SNP) | VAF 12/92 reads (13%) | catalogued as rs767406117, COSV60253039; called by muse, mutect2, varscan2
- ADCY6 | c.2921C>T p.S974L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs200070441, COSV57166826; called by muse, mutect2, varscan2
- ADGRG2 | c.967G>A p.E323K (on ENST00000379869 / NM_001079858.3; = p.E320K on NM_005756.4) | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV61338249; called by muse, mutect2, varscan2
- ADGRG2 | c.535G>A p.A179T (on ENST00000379869 / NM_001079858.3; = p.A176T on NM_005756.4) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.254); catalogued as COSV100491982, COSV61338254; called by muse, mutect2
- ADGRG4 | c.26A>C p.K9T | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV54952371; called by muse, mutect2
- ADGRL1 | c.2305G>A p.A769T (on ENST00000340736 / NM_001008701.3; = p.A764T on NM_014921.5) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.216); catalogued as COSV61564099; called by muse, mutect2
- ADGRL4 | c.2045T>A p.V682D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV66059263, COSV66060739; called by muse, mutect2
- ADGRL4 | c.1985del p.L662Yfs*28 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as rs770040543; called by mutect2, pindel
- ADH4 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV55500543; called by muse, mutect2
- AFF2 | c.3239A>C p.K1080T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53982440; called by muse, mutect2, varscan2
- AGAP6 | c.1511A>G p.E504G (on ENST00000374056 / NM_001365867.1; = p.E527G on NM_001077665.2) | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100929043, COSV100929072; called by muse, mutect2, varscan2
- AGL | c.4103C>T p.A1368V | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769401330, COSV54050415; called by muse, mutect2, varscan2
- AHCYL1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs768042207, COSV63208433; called by muse, mutect2, varscan2
- AK3 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 52/153 reads (34%) | catalogued as rs1161941370, COSV63346515; called by muse, varscan2
- AKAP17A | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.347); catalogued as COSV58308954; called by muse, mutect2
- AKNAD1 | c.2271G>A p.M757I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1302433397, COSV64171707; called by muse, mutect2, varscan2
- AKR1A1 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.561); catalogued as COSV61086563; called by muse, mutect2, varscan2
- ALG1 | c.962-1G>A p.X321_splice | Splice Site (SNP) | VAF 23/93 reads (25%) | catalogued as COSV52156702; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 90/308 reads (29%) | catalogued as rs1341338515; called by mutect2, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- AMHR2 | c.800dup p.P268Sfs*30 | Frame Shift Ins (INS) | VAF 17/75 reads (23%) | catalogued as rs748387033; called by mutect2, varscan2
- ANGPTL3 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1178161244, COSV52000374; called by muse, mutect2, varscan2
- ANK1 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs369968960; called by muse, mutect2, varscan2
- ANK3 | c.3748G>T p.G1250W (on ENST00000280772 / NM_001320874.2; = p.G384W on NM_001149.3) | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55050062; called by muse, mutect2, varscan2
- ANO7 | c.926G>A p.R309H (on ENST00000274979; = p.R255H on NM_001370694.2) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs757055477, COSV51469991; called by muse, mutect2, varscan2
- ANO9 | c.2275del p.A759Qfs*36 | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | catalogued as rs761382318; called by mutect2, pindel, varscan2
- AP2B1 | c.1024A>G p.M342V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV51998058; called by muse, mutect2, varscan2
- AP4B1 | c.1850C>A p.A617D | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs776964406, COSV56724042, COSV56725654; called by muse, mutect2, varscan2
- AP5B1 | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV57502522; called by muse, mutect2, varscan2
- AP5B1 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.386); catalogued as rs369106728; called by muse, mutect2, varscan2
- APBA1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.284); catalogued as rs953482604, COSV55224744; called by muse, mutect2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as rs546686089; called by mutect2, varscan2
- APOB | c.11654C>T p.A3885V | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV51929358; called by muse, mutect2, varscan2
- APOB | c.6905G>T p.G2302V | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV51927945, COSV51929374; called by muse, mutect2
- APOB | c.5901A>C p.K1967N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV51929386; called by muse, mutect2, varscan2
- APTX | c.546T>C p.V182= | Splice Region (SNP) | VAF 8/96 reads (8%) | catalogued as COSV58928161; called by muse, mutect2
- ARFGAP1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs1201442529, COSV62262664; called by muse, mutect2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 13/112 reads (12%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | catalogued as COSV51619799; called by pindel, varscan2*
- ARFGEF1 | c.3524A>G p.Y1175C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51605253; called by muse, mutect2, varscan2
- ARHGAP33 | c.2249T>C p.V750A | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV50120395; called by muse, mutect2, varscan2
- ARHGEF10 | c.1451C>T p.A484V (on ENST00000398564; = p.A459V on NM_014629.4) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs144726787; called by muse, mutect2, varscan2
- ARHGEF12 | c.1564A>T p.I522F | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63103434; called by muse, mutect2
- ARMC5 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369874589, COSV51655600; called by muse, mutect2, varscan2
- ARMC5 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs759686063, COSV51655615; called by muse, mutect2, varscan2
- ARSD | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs151213601, COSV54198929; called by muse, mutect2, varscan2
- ASAP1 | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs377058881, COSV63046258; called by muse, mutect2, varscan2
- ASB4 | c.1246T>C p.Y416H | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57943925; called by muse, mutect2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as rs747570359; called by mutect2, varscan2
- ASH1L | c.6892A>G p.K2298E (on ENST00000368346 / NM_001366177.2; = p.K2293E on NM_018489.3) | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV64206620; called by muse, mutect2, varscan2
- ASXL3 | c.6646C>T p.R2216W | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs935514846, COSV52461639, COSV52467723; called by muse, mutect2, varscan2
- ATM | c.7472G>T p.W2491L | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53734614, COSV53735811; called by muse, mutect2, varscan2
- ATP10A | c.848-1G>T p.X283_splice | Splice Site (SNP) | VAF 4/74 reads (5%) | catalogued as COSV100791180, COSV63515329; called by muse, mutect2
- ATP11C | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV59561009; called by muse, mutect2, varscan2
- ATP13A2 | c.2127-1G>T p.X709_splice | Splice Site (SNP) | VAF 11/79 reads (14%) | catalogued as COSV58699334; called by muse, mutect2, varscan2
- ATP13A3 | c.3079del p.W1027Gfs*31 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP13A4 | c.2493T>A p.S831R | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV61318015; called by muse, mutect2, varscan2
- ATP1A3 | c.862G>A p.A288T (on ENST00000545399 / NM_001256214.2; = p.A275T on NM_152296.5) | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs868987618, COSV57485725; called by muse, mutect2
- ATP2B2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as rs945844574, COSV59489385; called by muse, mutect2, varscan2
- ATP2B3 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs781827206, COSV54843028; called by muse, mutect2, varscan2
- ATP6V1B1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); catalogued as rs143516810; called by muse, mutect2, varscan2
- ATRX | c.3682C>T p.P1228S | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs782743875, COSV64873722; called by muse, mutect2, varscan2
- AVEN | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV60733234; called by muse, mutect2, varscan2
- AXL | c.836del p.P279Qfs*18 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | catalogued as COSV56571907; called by mutect2, pindel, varscan2
- B3GNT3 | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57952961; called by muse, mutect2
- BAG6 | c.2326G>A p.G776R (on ENST00000676571; = p.G729R on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.956); catalogued as COSV52989052; called by muse, mutect2
- BARHL1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs55836017, COSV55037260; called by muse, varscan2
- BBS7 | c.341+2T>C p.X114_splice | Splice Site (SNP) | VAF 17/68 reads (25%) | catalogued as COSV52655447; called by muse, mutect2, varscan2
- BCL11A | c.1853C>T p.T618M (on ENST00000335712 / NM_001365609.1; = p.T652M on NM_018014.4) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59626804; called by muse, mutect2, varscan2
- BCL9 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as rs782091140, COSV52342408; called by muse, mutect2, varscan2
- BFAR | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV55492883; called by muse, mutect2, varscan2
- BFSP2 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs747132237, COSV100183685; called by muse, mutect2, varscan2
- BGLAP | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1324662623, COSV52744631; called by mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 15/95 reads (16%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BPTF | c.2426G>A p.G809D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs751572182, COSV58834237; called by muse, mutect2, varscan2
- BRD1 | c.350T>G p.L117R | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53455859; called by muse, mutect2, varscan2
- BRMS1L | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV53762712; called by muse, mutect2, varscan2
- BRS3 | c.836T>A p.L279Q | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65710807; called by muse, varscan2
- C11orf52 | c.253A>C p.S85R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV53714461; called by muse, mutect2, varscan2
- C11orf80 | c.1804C>A p.L602I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.212); catalogued as COSV58992359; called by muse, mutect2
- C3orf18 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs577414859, COSV51750127; called by muse, mutect2, varscan2
- C3orf33 | c.868T>G p.F290V (on ENST00000340171 / NM_001308229.2; = p.F247V on NM_173657.2) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as COSV60896572; called by muse, mutect2, varscan2
- C4orf3 | c.194dup p.L65Ffs*20 | Frame Shift Ins (INS) | VAF 19/102 reads (19%) | catalogued as rs760121305; called by mutect2, pindel, varscan2
- C5 | c.935A>G p.Y312C | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.628); catalogued as COSV56325534; called by muse, mutect2
- C6 | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs758843180, COSV54707562; called by muse, mutect2, varscan2
- C6orf58 | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 16/285 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV61666257; called by muse, mutect2
- C7orf26 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs370863339; called by muse, mutect2, varscan2
- C8B | c.1629del p.I544Lfs*51 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs762770227; called by mutect2, pindel, varscan2
- CA9 | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.237); catalogued as rs151268469; called by muse, mutect2, varscan2
- CACNA1G | c.4864G>A p.G1622R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs1299615800, COSV100661075, COSV61722641; called by muse, mutect2, varscan2
- CACNA1G | c.6482C>T p.P2161L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as rs201791887; called by muse, mutect2, varscan2
- CACNB2 | c.1840C>T p.R614* (on ENST00000324631 / NM_201596.3; = p.R559* on NM_000724.4) | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as rs775467558, COSV56611781, COSV56616954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADPS2 | c.1439T>C p.V480A | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57355683; called by muse, mutect2, varscan2
- CAMKV | c.422T>C p.I141T | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56554666; called by muse, mutect2
- CAMSAP2 | c.2386A>G p.T796A (on ENST00000236925 / NM_001297707.2; = p.T785A on NM_203459.3) | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.289); catalogued as COSV52668654; called by muse, mutect2
- CAMTA1 | c.2930T>C p.M977T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs780237102, COSV100348295; called by mutect2, varscan2
- CAP1 | c.310T>A p.L104M | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV61223046; called by muse, mutect2
- CAP2 | c.1338G>T p.Q446H | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV57730932; called by muse, mutect2, varscan2
- CARD11 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs79513324, COSV67797979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARD9 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs767880614, COSV59996510; called by muse, mutect2, varscan2
- CARMIL2 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs771349402, COSV58024456; called by muse, mutect2, varscan2
- CARMIL3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57725562; called by muse, mutect2, varscan2
- CARMIL3 | c.2934G>T p.R978S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57725567; called by muse, mutect2
- CARMIL3 | c.3721A>G p.S1241G | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.931); catalogued as COSV53743261; called by muse, mutect2, varscan2
- CASP10 | c.1313T>G p.L438R (on ENST00000272879 / NM_032974.5; = p.L395R on NM_001230.5) | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53777234; called by muse, mutect2, varscan2
- CAVIN2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV58423643; called by muse, mutect2, varscan2
- CBLN2 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as COSV54050746; called by muse, mutect2
- CCDC105 | c.876G>A p.A292= | Splice Region (SNP) | VAF 7/24 reads (29%) | catalogued as rs748358227, COSV52963196; called by muse, mutect2, varscan2
- CCDC121 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV53113567; called by muse, mutect2
- CCDC141 | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs372583176; called by muse, mutect2, varscan2
- CCDC181 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); catalogued as COSV63156023, COSV63157632; called by muse, mutect2, varscan2
- CCDC39 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as rs745852520, COSV56480906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC42 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.527); catalogued as COSV53448405; called by muse, mutect2, varscan2
- CCDC57 | c.2702G>A p.G901D | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV60752103; called by muse, mutect2
- CCDC83 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs764835930, COSV54700115; called by muse, mutect2, varscan2
- CCDC92 | c.801dup p.I268Hfs*145 | Frame Shift Ins (INS) | VAF 10/76 reads (13%) | catalogued as rs773752200; called by mutect2, varscan2
- CCIN | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs531887638, COSV58724336; called by muse, mutect2, varscan2
- CCN5 | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV99509261; called by muse, mutect2
- CCNB3 | c.1490C>T p.T497I | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV52071425; called by muse, mutect2
- CCNF | c.1649del p.P550Rfs*80 | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | catalogued as COSV99563508; called by mutect2, pindel, varscan2
- CCNO | c.923A>G p.H308R | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV57004469; called by muse, mutect2, varscan2
- CCSER1 | c.689G>T p.C230F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV61417959; called by muse, mutect2, varscan2
- CCT6A | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV51905024; called by muse, mutect2
- CD177 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV100945911; called by muse, mutect2, varscan2
- CD8A | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1056431594, COSV52156816; called by muse, mutect2
- CDAN1 | c.2851G>T p.E951* | Nonsense Mutation (SNP) | VAF 12/141 reads (9%) | catalogued as COSV62331396; called by muse, mutect2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 14/109 reads (13%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC25B | c.1013G>A p.R338Q (on ENST00000245960 / NM_021873.3; = p.R324Q on NM_004358.4) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1416753572, COSV55655374; called by muse, mutect2
- CDC40 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs765638021, COSV55619031; called by mutect2, varscan2
- CDH10 | c.322dup p.T108Nfs*3 | Frame Shift Ins (INS) | VAF 8/57 reads (14%) | catalogued as rs748395403; called by mutect2, pindel, varscan2
- CDH11 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as COSV51755925; called by muse, mutect2
- CDH19 | c.959del p.K320Rfs*27 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as rs1322953086; called by mutect2, pindel, varscan2
- CDH23 | c.8444G>A p.R2815H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs376835293; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- CDH24 | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.94); catalogued as COSV52974610; called by muse, mutect2, varscan2
- CDHR1 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs142917517; called by muse, mutect2, varscan2
- CDX4 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100999106; called by muse, mutect2, varscan2
- CEACAM19 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs758680868, COSV62551892; called by muse, mutect2, varscan2
- CECR2 | c.2194G>T p.G732W (on ENST00000342247 / NM_001290047.2; = p.G549W on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV52838407; called by muse, mutect2, varscan2
- CELSR1 | c.4132T>A p.C1378S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53086280; called by muse, mutect2, varscan2
- CENPI | c.1700A>C p.K567T | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54501514; called by muse, mutect2
- CEP131 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs373880117, COSV53950511; called by muse, mutect2, varscan2
- CEP170B | c.1247G>A p.R416Q (on ENST00000453495; = p.R345Q on NM_015005.3) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs773293486, COSV69023827; called by muse, mutect2
- CEP250 | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV61168894; called by muse, mutect2, varscan2
- CEP83 | c.4G>A p.V2I | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.025); catalogued as rs568667768, COSV60407449; called by muse, mutect2, varscan2
- CERCAM | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773201835, COSV65710664; called by muse, varscan2
- CFAP54 | c.4797A>C p.K1599N | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV61571364; called by muse, mutect2, varscan2
- CH25H | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs754613437, COSV64092264; called by muse, mutect2, varscan2
- CHD3 | c.5701C>T p.R1901C (on ENST00000330494 / NM_001005273.3; = p.R1867C on NM_005852.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765857922, COSV57873582; called by muse, mutect2, varscan2
- CHD4 | c.1792C>T p.R598C (on ENST00000357008 / NM_001363606.2; = p.R611C on NM_001273.5) | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV58897110; called by muse, mutect2, varscan2
- CHD5 | c.3547T>C p.S1183P | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52411041; called by muse, mutect2, varscan2
- CHD6 | c.3170A>G p.Y1057C | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58555492; called by muse, mutect2
- CHPF2 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs374488900; called by muse, mutect2, varscan2
- CHRM3 | c.1580A>C p.N527T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.484); catalogued as COSV55084906; called by muse, mutect2
- CHRNA2 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53556971; called by muse, mutect2
- CHST8 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.034); catalogued as COSV52857584; called by muse, mutect2, varscan2
- CIITA | c.1493T>C p.L498P | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs886051640, COSV60855386; ClinVar: uncertain significance; called by muse, mutect2
- CIITA | c.1962dup p.G655Rfs*94 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs778982759; called by mutect2, varscan2
- CIITA | c.3305T>C p.V1102A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV60855398; called by mutect2, varscan2
- CKMT2 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54172573; called by muse, mutect2
- CLDN6 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV58509188; called by muse, mutect2, varscan2
- CLEC1A | c.707G>A p.C236Y | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59531353; called by muse, mutect2, varscan2
- CLEC4A | c.284del p.N95Ifs*49 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs760557093; called by mutect2, varscan2
- CLIP4 | c.1185del p.D396Ifs*19 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs1332364476; called by mutect2, pindel, varscan2
- CLMN | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV54180554; called by muse, mutect2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 41/122 reads (34%) | catalogued as rs369752219; called by mutect2, varscan2
- CNGB3 | c.477A>C p.E159D | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.225); catalogued as COSV60686870; called by muse, mutect2
- CNMD | c.71del p.P24Rfs*6 | Frame Shift Del (DEL) | VAF 17/94 reads (18%) | catalogued as rs768157613; called by mutect2, pindel, varscan2
- COG3 | c.1616C>A p.P539H | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV63071904; called by muse, mutect2, varscan2
- COG5 | c.2027A>C p.Q676P (on ENST00000347053 / NM_001379512.1; = p.Q697P on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51746287; called by muse, mutect2, varscan2
- COL14A1 | c.5144dup p.G1716Wfs*45 | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | catalogued as rs1405316074; called by mutect2, pindel, varscan2
- COL17A1 | c.3605C>T p.S1202L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs758851971, COSV62225168; called by muse, mutect2, varscan2
- COL20A1 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as rs779629994, COSV58914150, COSV58923877; called by muse, mutect2, varscan2
- COL22A1 | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57329870; called by muse, mutect2
- COL4A3 | c.4826G>A p.R1609Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1380878336, COSV67414252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A5 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV60355555; called by muse, mutect2, varscan2
- COL7A1 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.593); catalogued as rs371991224; called by muse, mutect2, varscan2
- COPB2 | c.1802G>T p.R601M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV60812156; called by muse, mutect2, varscan2
- COQ8B | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.048); catalogued as rs1174764227, COSV54686264; called by muse, mutect2, varscan2
- CPD | c.3935T>C p.L1312S | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56711698; called by muse, mutect2, varscan2
- CPNE7 | c.1688G>C p.G563A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52011727; called by muse, mutect2, varscan2
- CPT1A | c.1805C>T p.T602M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1176189631, COSV55754202; called by muse, mutect2, varscan2
- CPXM2 | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs78179127; called by muse, mutect2, varscan2
- CR1 | c.4054C>T p.P1352S | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.165); catalogued as rs915609384, COSV65457088; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs747248693; called by mutect2, varscan2
- CSF1R | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1318254419, COSV53831916; called by muse, mutect2, varscan2
- CSMD2 | c.8531G>A p.G2844D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs867317039, COSV53895235; called by muse, mutect2, varscan2
- CSNK1D | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV53923593; called by muse, mutect2, varscan2
- CSRNP2 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1377509751, COSV57334006; called by muse, mutect2, varscan2
- CSTF2 | c.501A>T p.Q167H | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63376177; called by muse, mutect2
- CTCF | c.1518+1G>A p.X506_splice | Splice Site (SNP) | VAF 12/66 reads (18%) | catalogued as COSV50463918, COSV50486586; called by muse, mutect2, varscan2
- CTTN | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57231036, COSV57233523; called by muse, mutect2
- CUL1 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV57387636; called by muse, mutect2, varscan2
- CUL1 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57387649; called by muse, mutect2, varscan2
- CUL3 | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 114/391 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.13); catalogued as rs774263455, COSV52362831; called by muse, mutect2, varscan2
- CUX1 | c.1125+2T>C p.X375_splice (on ENST00000292535 / NM_181552.4; = p.X386_splice on NM_001913.5) | Splice Site (SNP) | VAF 5/40 reads (13%) | catalogued as COSV52894843; called by muse, mutect2, varscan2
- CUX2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs760244153, COSV55627723; called by muse, mutect2, varscan2
- CWF19L2 | c.2110C>T p.R704W | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs750590112, COSV56510474; called by muse, mutect2, varscan2
- CX3CL1 | c.493T>C p.S165P | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV50055578; called by muse, mutect2, varscan2
- CXCR2 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199777583; called by muse, mutect2, varscan2
- CYP17A1 | c.1001A>G p.Q334R | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV64004819; called by muse, mutect2, varscan2
- CYP2S1 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs376137528, COSV59505113; called by muse, mutect2, varscan2
- CYP4F11 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.564); catalogued as rs776689267, COSV56126278; called by muse, mutect2, varscan2
- CYP4F2 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs749333709, COSV50000674, COSV50002722; called by muse, mutect2, varscan2
- DAP3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs751431768, COSV58018995; called by muse, mutect2, varscan2
- DAZAP2 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66312908; called by muse, mutect2, varscan2
- DCAF12L1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1382144079, COSV64421404; called by muse, mutect2, varscan2
- DCAF12L2 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63580837; called by muse, mutect2, varscan2
- DCTN6 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55317383; called by muse, mutect2, varscan2
- DDC | c.315G>T p.W105C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181496880, COSV63564507, COSV63567810; called by muse, mutect2, varscan2
- DDX23 | c.1829C>A p.P610H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99974810; called by muse, mutect2, varscan2
- DDX39B | c.736-3dup | Splice Region (INS) | VAF 8/36 reads (22%) | catalogued as rs755280697; called by mutect2, varscan2
- DDX49 | c.1021C>A p.R341S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55355367; called by muse, mutect2, varscan2
- DDX50 | c.1732C>T p.R578* | Nonsense Mutation (SNP) | VAF 27/137 reads (20%) | catalogued as rs767510758, COSV65291922; called by muse, mutect2, varscan2
- DENND4A | c.966dup p.D323* | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | catalogued as rs375223942; called by mutect2, varscan2
- DFFB | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs532234992, COSV59496205; called by mutect2, varscan2
- DGCR8 | c.1967C>A p.A656E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as COSV100707893; called by muse, mutect2, varscan2
- DHDDS | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV52575959; called by muse, mutect2, varscan2
- DHX8 | c.2108A>G p.K703R | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV52251901; called by muse, mutect2
- DICER1 | c.4879G>A p.A1627T | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV58617198; called by muse, mutect2, varscan2
- DIO2 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70444970, COSV70445363; called by muse, mutect2, varscan2
- DISP1 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766010478, COSV52656759; called by muse, mutect2, varscan2
- DIXDC1 | c.1591G>A p.D531N (on ENST00000440460 / NM_001037954.4; = p.D320N on NM_033425.4) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs782574818, COSV59461493, COSV59461506; called by muse, mutect2, varscan2
- DKK1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64760089; called by muse, mutect2, varscan2
- DLGAP1 | c.1528T>C p.S510P | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.775); catalogued as COSV59793856; called by muse, mutect2, varscan2
- DLST | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53165798; called by muse, mutect2
- DLX5 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as rs758348857, COSV56032081; called by muse, mutect2, varscan2
- DMAC1 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV64065710; called by muse, mutect2
- DMXL2 | c.5530C>A p.L1844I | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51842884; called by muse, mutect2, varscan2
- DNAAF5 | c.2284G>A p.A762T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as rs377559314; called by muse, mutect2, varscan2
- DNAH11 | c.1779C>A p.S593R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.271); catalogued as COSV100178587; called by muse, mutect2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH2 | c.10291G>A p.A3431T | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs774202574, COSV66718020; called by muse, mutect2, varscan2
- DNAH5 | c.1952T>C p.L651P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54213563; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAI3 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 32/432 reads (7%) | catalogued as rs141494762, COSV54001454; called by muse, mutect2
- DNAJC3 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV65130948; called by muse, mutect2
- DNASE1 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV55912900; called by muse, mutect2, varscan2
- DNM3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs527384140, COSV62455336; called by muse, mutect2, varscan2
- DNMT3B | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs764722946, COSV52416359; called by muse, mutect2, varscan2
- DOCK1 | c.5425G>A p.A1809T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs748393302, COSV54734269; called by muse, mutect2, varscan2
- DOCK2 | c.5086C>T p.R1696W | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs980056604, COSV56944050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOK2 | c.649T>G p.C217G | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52388009; called by muse, mutect2, varscan2
- DPYSL3 | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV58325297; called by muse, mutect2
- DSCAM | c.5662G>A p.A1888T | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68023697; called by muse, mutect2, varscan2
- DSCAM | c.3577G>A p.A1193T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs201680585, COSV101259722; called by muse, mutect2, varscan2
- DSG4 | c.65A>G p.N22S | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.044); catalogued as COSV57389686; called by muse, mutect2, varscan2
- DTNA | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.495); catalogued as rs199556035, COSV52008314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUSP10 | c.547T>C p.Y183H | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60457120; called by muse, mutect2, varscan2
- EBNA1BP2 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.457); catalogued as rs756079131, COSV52539608; called by muse, mutect2, varscan2
- ECE1 | c.1390-2A>C p.X464_splice | Splice Site (SNP) | VAF 14/158 reads (9%) | catalogued as COSV99941657; called by muse, mutect2
- EDARADD | c.61+2T>C p.X21_splice | Splice Site (SNP) | VAF 10/110 reads (9%) | catalogued as COSV62061930; called by muse, mutect2
- EDARADD | c.197G>A p.R66Q (on ENST00000334232 / NM_145861.4; = p.R56Q on NM_080738.4) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1163649519, COSV62061939; called by muse, varscan2
- EDARADD | c.610C>T p.P204S (on ENST00000334232 / NM_145861.4; = p.P194S on NM_080738.4) | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100512676; called by muse, mutect2
- EEA1 | c.2944C>T p.L982F | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV59283863; called by muse, mutect2, varscan2
- EEF2 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867219501, COSV58578803, COSV58578919; called by muse, mutect2, varscan2
- EIF2B5 | c.864G>T p.E288D (on ENST00000647909; = p.E280D on NM_003907.3) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56604063; called by mutect2, varscan2
- EIF4G2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV60596622; called by muse, mutect2, varscan2
- ELK1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV55952386; called by muse, mutect2
- ELP2 | c.1121A>G p.N374S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV60849801; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 44/175 reads (25%) | catalogued as rs759858342; called by mutect2, pindel, varscan2
- EMX2 | c.332C>A p.S111* | Nonsense Mutation (SNP) | VAF 12/234 reads (5%) | catalogued as COSV71294387, COSV71294478; called by muse, mutect2
- ENGASE | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs765743001, COSV56134874; called by muse, mutect2, varscan2
- ENTPD4 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs755215378, COSV62268605; called by muse, mutect2, varscan2
- ENTPD8 | c.1367C>T p.A456V (on ENST00000371506 / NM_001033113.2; = p.A419V on NM_198585.3) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs757857009, COSV58161077; called by muse, mutect2, varscan2
- EPB41 | c.1744del p.T582Qfs*11 (on ENST00000343067 / NM_001166005.2; = p.T373Qfs*11 on NM_004437.4) | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | catalogued as COSV58042400; called by mutect2, pindel, varscan2
- EPB41L4B | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201249269, COSV65796261; called by muse, mutect2, varscan2
- EPHB4 | c.2000T>C p.I667T | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62268341; called by muse, mutect2
- ERAP2 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV65939205; called by muse, mutect2, varscan2
- ERC2 | c.2456C>A p.T819N | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.345); catalogued as COSV55610492, COSV55625287; called by muse, mutect2
- ERCC6L2 | c.1339A>G p.S447G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV56629376; called by muse, mutect2, varscan2
- ESPL1 | c.5839A>C p.S1947R | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54475513; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | catalogued as rs775950025; called by mutect2, varscan2
- EVPL | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs1567911278, COSV56908934; called by muse, mutect2, varscan2
- EVX2 | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV57962825; called by muse, mutect2, varscan2
- EXOSC9 | c.592T>G p.F198V | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV54665426; called by muse, mutect2, varscan2
- FAAP100 | c.2175C>T p.G725= | Splice Region (SNP) | VAF 4/16 reads (25%) | catalogued as rs758795190, COSV59884544; called by mutect2, varscan2
- FAM120C | c.1273A>G p.R425G | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.302); catalogued as COSV60258313; called by muse, mutect2, varscan2
- FAM133A | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59074442; called by muse, mutect2
- FAM155B | c.879G>A p.W293* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV52935600; called by muse, mutect2, varscan2
- FAM166C | c.584G>A p.C195Y | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.135); catalogued as COSV56599908; called by muse, mutect2, varscan2
- FAM171B | c.728T>C p.F243S | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as COSV59001902; called by muse, mutect2
- FAM214A | c.2372T>C p.V791A | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.114); catalogued as COSV55923099; called by muse, mutect2, varscan2
- FAM234B | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV52193683; called by muse, mutect2, varscan2
- FAM71C | c.408dup p.Q137Tfs*24 | Frame Shift Ins (INS) | VAF 20/70 reads (29%) | catalogued as rs762930877; called by mutect2, varscan2
- FANCM | c.3286C>T p.P1096S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV57498829; called by muse, mutect2
- FBF1 | c.1780G>A p.E594K (on ENST00000586717; = p.E608K on NM_001319193.1) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59864076; called by muse, mutect2, varscan2
- FBH1 | c.415C>T p.R139W (on ENST00000362091 / NM_178150.3; = p.R190W on NM_032807.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs150913018; called by muse, mutect2, varscan2
- FBN3 | c.4730del p.G1577Vfs*72 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | catalogued as COSV54462674; called by mutect2, pindel, varscan2
- FBXL13 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as rs754512148, COSV57536267; called by mutect2, varscan2
- FBXO15 | c.1444A>T p.I482F | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54043844; called by muse, mutect2
- FBXO8 | c.746T>C p.L249S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67031161; called by muse, mutect2
- FBXW8 | c.111+2T>C p.X37_splice (on ENST00000309909; = p.X75_splice on NM_012174.1) | Splice Site (SNP) | VAF 10/90 reads (11%) | catalogued as COSV59297699; called by muse, varscan2
- FCAR | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 58/698 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV62029026; called by muse, mutect2
- FCGR2A | c.196C>T p.R66C (on ENST00000271450 / NM_001136219.3; = p.R65C on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1257003455, COSV54837274; called by muse, mutect2, varscan2
- FCSK | c.3043del p.H1015Tfs*19 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | catalogued as rs754711319; called by mutect2, pindel, varscan2
- FEZ2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1244443425, COSV59906272; called by muse, mutect2, varscan2
- FGA | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100120298, COSV100120770; called by muse, mutect2
- FGD1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV64308378; called by muse, mutect2, varscan2
- FGGY | c.406T>C p.Y136H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV58029797; called by muse, mutect2, varscan2
- FHOD1 | c.2383C>T p.R795W | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs772102709, COSV50759543; called by muse, mutect2, varscan2
- FKBP9 | c.384dup p.N129Qfs*7 | Frame Shift Ins (INS) | VAF 23/101 reads (23%) | catalogued as rs752076602; called by mutect2, varscan2
- FLII | c.3798G>T p.K1266N | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV57496980; called by muse, mutect2
- FLNC | c.4576C>T p.R1526C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs746275035, COSV57953023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.4699C>T p.R1567W | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs369842920; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMN2 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.041); catalogued as rs780698754, COSV60424386; called by muse, mutect2, varscan2
- FNBP1 | c.197A>C p.K66T | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV63086117; called by muse, mutect2
- FNDC3B | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61039625; called by muse, mutect2
- FOSL2 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV53103849; called by muse, mutect2
- FOXD4L3 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1188596449; called by mutect2, varscan2
- FOXG1 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57395324; called by muse, mutect2, varscan2
- FOXJ3 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs201486136, COSV62359697; called by muse, mutect2
- FOXN3 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs1260981018, COSV54306300; called by muse, mutect2, varscan2
- FOXQ1 | c.467del p.F156Sfs*247 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | catalogued as rs1259007659, COSV57259274; called by mutect2, pindel, varscan2
- FOXR1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV57651667, COSV57651713; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs749552940, COSV58548047; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 14/101 reads (14%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FSCN3 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs371404003; called by muse, mutect2, varscan2
- FZD9 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60669814; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | catalogued as rs758551787; called by mutect2, varscan2
- GBP1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV65083082; called by muse, mutect2
- GCC1 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs765520352, COSV58462142; called by muse, mutect2, varscan2
- GIPR | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54423308; called by muse, mutect2, varscan2
- GKN2 | c.205-1G>A p.X69_splice | Splice Site (SNP) | VAF 22/74 reads (30%) | catalogued as rs1405091504, COSV100187659, COSV61031035; called by muse, mutect2, varscan2
- GLG1 | c.1192C>T p.L398F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52665180; called by muse, mutect2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 20/203 reads (10%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel
- GLI3 | c.1870C>A p.L624I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67886715; called by muse, mutect2, varscan2
- GLI3 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs756581886, COSV67886717; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLIPR1 | c.436A>G p.S146G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56990272; called by muse, mutect2, varscan2
- GLRA4 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as rs777996283, COSV60327413, COSV60327781; called by muse, mutect2, varscan2
- GMPPA | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745743360, COSV58006397; called by muse, mutect2, varscan2
- GORASP2 | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV52201291; called by muse, mutect2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 36/116 reads (31%) | catalogued as rs370114090; called by mutect2, varscan2
- GPANK1 | c.800dup p.W268Lfs*12 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs765697080; called by mutect2, varscan2
- GPD1 | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 12/195 reads (6%) | catalogued as COSV56547660; called by muse, mutect2
- GPM6B | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374251909, COSV57421769; called by muse, mutect2, varscan2
- GPR1 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV67976618; called by muse, mutect2
- GPR107 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV61278182; called by muse, mutect2, varscan2
- GPR137 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV57401514, COSV57402558; called by muse, mutect2, varscan2
- GPSM1 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs782376031, COSV52516987, COSV52517307; called by muse, mutect2, varscan2
- GPX1 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1276125010, COSV69042051; called by muse, mutect2, varscan2
- GRAMD1B | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1331085646, COSV59202167; called by muse, mutect2
- GRB7 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV58446878; called by muse, mutect2, varscan2
- GRIK4 | c.1277A>C p.N426T | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV70800092; called by muse, mutect2
- GRM1 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51136069; called by muse, mutect2, varscan2
- GRM3 | c.2075G>C p.C692S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.928); catalogued as COSV64469086; called by muse, mutect2
- GSDMA | c.1145T>C p.F382S | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as COSV52856920; called by muse, mutect2, varscan2
- GSG1L | c.475G>A p.E159K (on ENST00000447459 / NM_001109763.2; = p.E4K on NM_144675.2) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs779884306, COSV66576740; called by muse, mutect2, varscan2
- GTPBP1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV53283863; called by muse, mutect2
- GUCY1A1 | c.2033G>A p.G678D | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.218); catalogued as rs768418830, COSV56650401; called by muse, mutect2, varscan2
- GUSB | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV59221254; called by muse, mutect2, varscan2
- HADHA | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204190984, CM994328, COSV66106823; called by muse, mutect2, varscan2
- HAO1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV66491480; called by muse, mutect2, varscan2
- HAS2 | c.894T>G p.D298E | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV58262788; called by muse, mutect2
- HAT1 | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV51362070; called by muse, mutect2
- HAUS8 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757762377, COSV53725689; called by muse, mutect2, varscan2
- HCFC1 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); catalogued as COSV60070603; called by muse, varscan2
- HDAC6 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs199596944, COSV61927902; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 12/25 reads (48%) | catalogued as COSV100625709; called by mutect2, varscan2
- HEATR3 | c.520A>C p.S174R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV53528633; called by muse, varscan2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 11/124 reads (9%) | catalogued as rs771658394; called by mutect2, pindel
- HECTD4 | c.1895A>C p.Y632S | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV61178426; called by muse, mutect2
- HERC2 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV55314841; called by muse, mutect2, varscan2
- HERPUD1 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV55861738; called by muse, mutect2
- HNRNPA1 | c.437G>T p.R146M | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52936125, COSV52938395; called by muse, mutect2, varscan2
- HNRNPAB | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV57423420; called by muse, varscan2
- HNRNPR | c.851A>G p.D284G | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56420656; called by muse, mutect2, varscan2
- HOXD1 | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV58923263; called by muse, mutect2
- HR | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs779765704, COSV57191249; called by muse, mutect2
- HS3ST5 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs776534627, COSV57137383; called by muse, mutect2, varscan2
- HSPB8 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs140173724; called by muse, mutect2, varscan2
- HTR1B | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as rs968574182, COSV64051119; called by muse, mutect2, varscan2
- HTR5A | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs542112656, COSV55281698; called by mutect2, varscan2
- HTR7 | c.1421del p.K474Rfs*3 (on ENST00000336152 / NM_019859.4; = p.G442Vfs*6 on NM_000872.5) | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | catalogued as COSV53287248; called by mutect2, pindel, varscan2
- HUWE1 | c.7814G>A p.R2605H | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs142176360, COSV53339573; called by muse, mutect2, varscan2
- HYDIN | c.14998A>G p.K5000E | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV66638086; called by muse, mutect2, varscan2
- IFI16 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138795047; called by muse, mutect2, varscan2
- IFT140 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as rs199532257, COSV68486820; called by muse, mutect2, varscan2
- IGFBP1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51874399; called by muse, mutect2
- IGHV3-20 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 80/319 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.037); catalogued as rs782449916; called by muse, mutect2, varscan2
- IGSF22 | c.239A>G p.E80G | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV60032194; called by muse, mutect2
- IKBKB | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as rs200322650, COSV60596423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL13RA1 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs775001455, COSV65424217, COSV65424292; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56248018; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1726A>T p.S576C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV56248030; called by muse, mutect2, varscan2
- IMPDH1 | c.1044G>T p.K348N (on ENST00000470772 / NM_001142573.2; = p.K434N on NM_000883.4) | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.753); catalogued as COSV58315454; called by muse, mutect2
- INPP4A | c.2905G>A p.E969K (on ENST00000074304 / NM_001134224.1; = p.E930K on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs529481819, COSV50787245; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IPO8 | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56240398; called by muse, mutect2
- IQCK | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs560311228, COSV57521975; called by muse, mutect2, varscan2
- IRAK1 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as rs782768715, COSV64110331; called by muse, mutect2, varscan2
- IRX6 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV51859727, COSV99306213; called by muse, varscan2
- ISLR2 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.063); catalogued as COSV62301828; called by muse, mutect2
- ITGA1 | c.2861G>T p.S954I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.332); catalogued as COSV50878633; called by muse, mutect2, varscan2
- ITGA2B | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV52231876; called by muse, mutect2, varscan2
- ITGAL | c.3409G>A p.A1137T | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.03); catalogued as COSV63321009; called by muse, mutect2, varscan2
- ITPKB | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs573808314, COSV55259094, COSV55270905; called by muse, mutect2, varscan2
- ITPR3 | c.4519C>T p.R1507C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs746407544, COSV65407285; called by muse, mutect2, varscan2
- JAK1 | c.2195G>A p.G732D | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.885); catalogued as COSV61089325; called by muse, varscan2
- JMJD7-PLA2G4B | c.110C>G p.T37S | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs200665426, COSV59823063; called by muse, mutect2
- KANK1 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.724); catalogued as rs139689422; called by mutect2, varscan2
- KANSL1L | c.2749C>T p.R917* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs764005212, COSV55990622; called by muse, mutect2, varscan2
- KAZALD1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV64630059; called by muse, mutect2
- KCNB2 | c.128del p.G43Afs*40 | Frame Shift Del (DEL) | VAF 19/119 reads (16%) | catalogued as COSV73053085; called by mutect2, pindel, varscan2
- KCNC4 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63925359; called by muse, mutect2
- KCNH3 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as rs370141350; called by muse, mutect2
- KCNJ4 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 89/291 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV57856566; called by muse, mutect2, varscan2
- KCNK16 | c.629T>A p.L210H | Missense Mutation (SNP) | VAF 19/301 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64677601; called by muse, mutect2
- KCNQ2 | c.1505C>T p.A502V (on ENST00000359125 / NM_172107.4; = p.A474V on NM_004518.6) | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as rs375264483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNQ3 | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV66466888; called by muse, mutect2, varscan2
- KCNT1 | c.1037G>A p.R346H (on ENST00000488444; = p.R365H on NM_020822.3) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs1044487630, COSV53696606; called by muse, mutect2, varscan2
- KCNT2 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV54071371; called by muse, mutect2
- KDM2B | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV65639142; called by muse, mutect2
- KDM4B | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.02); catalogued as rs756754407, COSV50208468; called by muse, mutect2, varscan2
- KDM5C | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV62890888; called by muse, mutect2
- KIAA0753 | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV63817038; called by muse, varscan2
- KIAA1217 | c.463del p.D155Mfs*19 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs1264299382; called by mutect2, pindel, varscan2
- KIAA1217 | c.4771A>G p.T1591A | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1174712098, COSV56814610; called by muse, mutect2, varscan2
- KIDINS220 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 9/151 reads (6%) | catalogued as COSV56751696; called by muse, mutect2
- KIF16B | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61700869; called by muse, mutect2, varscan2
- KIF1C | c.1322T>C p.M441T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV57903696; called by muse, mutect2, varscan2
- KIF20A | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV50146108; called by muse, mutect2
- KIF2B | c.1779A>C p.K593N | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV52128672, COSV52136221; called by muse, mutect2
- KIF5A | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs1390179670, COSV54052875, COSV99673651; called by muse, mutect2, varscan2
- KIRREL1 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs138458053; called by muse, mutect2, varscan2
- KLC2 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as rs747748117, COSV100270581, COSV57581996; called by muse, mutect2, varscan2
- KLF5 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV66613939; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KLHL7 | c.1106C>T p.P369L (on ENST00000339077 / NM_001031710.3; = p.P321L on NM_018846.5) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV100178162, COSV59160508; called by muse, mutect2, varscan2
- KLHL8 | c.216+2T>C p.X72_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV56747277; called by muse, mutect2
- KLK15 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs139927076, COSV56826391; called by muse, mutect2, varscan2
- KLKB1 | c.405A>C p.E135D | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as COSV52994665; called by muse, mutect2, varscan2
- KMT2C | c.8602A>G p.T2868A | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51422217; called by muse, mutect2
- KMT2C | c.7825C>T p.R2609* | Nonsense Mutation (SNP) | VAF 18/147 reads (12%) | catalogued as COSV51419035; called by muse, mutect2, varscan2
- KMT5B | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58564911; called by muse, mutect2, varscan2
- KNDC1 | c.3200C>T p.T1067I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV58833891; called by muse, mutect2
- KRCC1 | c.547del p.S183Afs*7 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs1326358542; called by mutect2, varscan2
- KRT23 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as COSV52927357; called by muse, mutect2, varscan2
- KRT6C | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.165); catalogued as rs772675969, COSV52877067; called by muse, mutect2, varscan2
- KRT9 | c.1861T>C p.S621P | Missense Mutation (SNP) | VAF 14/93 reads (15%) | PolyPhen benign (0.007); catalogued as COSV55852128; called by muse, varscan2
- KRTAP1-1 | c.396del p.C133Afs*4 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs767482453; called by mutect2, pindel, varscan2
- KRTAP1-1 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV60398064; called by muse, mutect2
- KRTAP19-6 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.026); catalogued as COSV100473989, COSV61843836; called by muse, mutect2
- LAMB3 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as COSV61915981; called by muse, mutect2, varscan2
- LAPTM4A | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV51532152; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 36/116 reads (31%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCAT | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV50452393; called by muse, mutect2, varscan2
- LCK | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs1557588210, COSV60739292; called by muse, mutect2, varscan2
- LCN2 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as COSV52979936; called by muse, mutect2
- LCT | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1305451365, COSV51545072; called by muse, mutect2, varscan2
- LETMD1 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 15/161 reads (9%) | catalogued as COSV50396992; called by muse, mutect2
- LHPP | c.532-1G>T p.X178_splice | Splice Site (SNP) | VAF 19/57 reads (33%) | catalogued as COSV64328642, COSV64328733; called by muse, mutect2, varscan2
- LILRA5 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs191598155, COSV56642061; called by muse, mutect2
- LINGO3 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV101347239; called by muse, mutect2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs780042765; called by mutect2, varscan2
- LLGL2 | c.381del p.S128Vfs*78 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs1198259479; called by mutect2, pindel, varscan2
- LMCD1 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192293695, COSV50087650; called by muse, mutect2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | catalogued as rs746133895; called by mutect2, varscan2
- LPA | c.4289C>T p.A1430V | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as rs370793685, COSV60298183; called by muse, mutect2, varscan2
- LRCH4 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1318708986, COSV59642745; called by muse, mutect2, varscan2
- LRFN5 | c.1136A>G p.H379R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV53249352; called by muse, mutect2, varscan2
- LRRC43 | c.1391T>G p.V464G | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60288763; called by muse, mutect2, varscan2
- LRRC4B | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.282); catalogued as COSV65349574; called by muse, mutect2, varscan2
- LRRC59 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV56814088; called by muse, mutect2, varscan2
- LRRC7 | c.1693G>A p.A565T (on ENST00000651989 / NM_001370785.2; = p.A532T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV50429736; called by muse, mutect2, varscan2
- LRRIQ1 | c.1470del p.K490Nfs*28 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as COSV101280733; called by mutect2, pindel
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | catalogued as rs756089224; called by mutect2, varscan2
- LTN1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs375416726; called by muse, mutect2, varscan2
- MAGEA12 | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV63294483; called by muse, mutect2
- MAGEB18 | c.722G>T p.R241M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57463574; called by muse, mutect2
- MAGEC3 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV53577892; called by muse, mutect2, varscan2
- MAGEL2 | c.3230T>C p.L1077S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); catalogued as rs751206981, COSV58566378; called by muse, mutect2, varscan2
- MAGI3 | c.2602A>G p.T868A | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56832018; called by muse, mutect2
- MAN2B1 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55470847; called by muse, mutect2, varscan2
- MAN2B2 | c.2732G>A p.R911H | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs370359547, COSV53451697; called by muse, mutect2, varscan2
- MAP3K11 | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs779565351, COSV58418896; called by muse, varscan2
- MAP4 | c.1232T>C p.V411A | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV64237707; called by muse, mutect2
- MAPK15 | c.1538del p.G513Vfs*? | Frame Shift Del (DEL) | VAF 22/127 reads (17%) | catalogued as rs782558070; called by mutect2, pindel, varscan2
- MAPK3 | c.70del p.V24Sfs*8 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs1338865633, COSV53775573; called by mutect2, pindel
- MAPK8IP3 | c.3644C>T p.A1215V | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.022); catalogued as rs201201035, COSV51599578; called by muse, mutect2, varscan2
- MARCHF9 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56984329; called by muse, mutect2, varscan2
- MARCKSL1 | c.310T>C p.S104P | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as COSV61481921; called by muse, mutect2, varscan2
- MATN4 | c.1451G>A p.R484Q (on ENST00000372754; = p.R443Q on NM_003833.4) | Missense Mutation (SNP) | VAF 6/93 reads (6%) | PolyPhen probably damaging (0.999); catalogued as COSV100637170, COSV61350811; called by muse, mutect2
- MB21D2 | c.647del p.N216Mfs*11 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs748185381; called by mutect2, pindel, varscan2
- MC1R | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as rs1301300922, COSV59624837; called by muse, mutect2
- MCC | c.1568G>A p.S523N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV56726710; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCOLN1 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV51174483; called by muse, mutect2, varscan2
- MDGA2 | c.2621G>A p.R874Q (on ENST00000399232 / NM_001113498.2; = p.R576Q on NM_182830.4) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1049317974, COSV62084032; called by muse, mutect2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs1180255648; called by mutect2, varscan2
- MED12L | c.6200A>G p.Q2067R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.775); catalogued as COSV56373291; called by mutect2, varscan2
- MEGF9 | c.760T>C p.C254R | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64235010; called by muse, mutect2, varscan2
- MEI1 | c.3485C>A p.A1162D | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV55901845; called by muse, mutect2
- MEIS2 | c.235G>A p.A79T (on ENST00000561208 / NM_170675.5; = p.A66T on NM_002399.3) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV54932163, COSV54933094; called by muse, mutect2, varscan2
- MELTF | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56379515; called by muse, mutect2
- MFN2 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52421311; called by muse, mutect2, varscan2
- MFSD2B | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV57854245; called by muse, mutect2
- MIA3 | c.1242T>A p.D414E | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60511420; called by muse, mutect2, varscan2
- MICU2 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs561267095, COSV66673510; called by muse, mutect2, varscan2
- MINDY4 | c.419+2T>C p.X140_splice | Splice Site (SNP) | VAF 3/29 reads (10%) | catalogued as COSV54672617; called by muse, mutect2
- MMP17 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146831311; called by muse, mutect2, varscan2
- MMP21 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as COSV64289046; called by muse, mutect2
- MORC4 | c.2680C>T p.R894W | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs747662628, COSV55240017; called by muse, mutect2, varscan2
- MORF4L1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 44/62 reads (71%) | catalogued as rs1256023054, COSV58704072; called by muse, mutect2, varscan2
- MOS | c.722G>A p.G241D | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61336073; called by muse, mutect2, varscan2
- MPP1 | c.1249_1251del p.K417del | In Frame Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs1252010732; called by mutect2, pindel, varscan2
- MPP2 | c.502C>T p.R168C (on ENST00000461854 / NM_001278372.2; = p.R144C on NM_005374.5) | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs936018719, COSV52234502; called by muse, mutect2
- MRGPRX2 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 22/263 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV61673986; called by muse, mutect2
- MROH8 | c.952C>A p.L318M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.988); catalogued as COSV54118566; called by muse, mutect2, varscan2
- MROH9 | c.1519A>C p.S507R | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs74760081, COSV63010291, COSV63010569; called by muse, mutect2, varscan2
- MRPL3 | c.560T>A p.I187N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV53913846; called by muse, mutect2, varscan2
- MRPL49 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.356); catalogued as rs748704915, COSV53695027; called by muse, mutect2, varscan2
- MRTFB | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57956860; called by muse, mutect2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as rs759847587; called by mutect2, varscan2
- MTHFD2L | c.478A>G p.N160D (on ENST00000395759 / NM_001144978.2; = p.N102D on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV57466562; called by muse, varscan2
- MTHFR | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs760886915, CM013905, COSV57171840; called by muse, mutect2, varscan2
- MTR | c.2156T>C p.V719A | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63964268; called by muse, mutect2, varscan2
- MTRF1 | c.1094A>C p.K365T | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV65263120; called by muse, mutect2, varscan2
- MUC17 | c.3982C>T p.P1328S | Missense Mutation (SNP) | VAF 85/331 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as rs1422156360, COSV60283813; called by muse, mutect2, varscan2
- MUC17 | c.6125G>A p.R2042Q | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs373744994, COSV100075493; called by muse, mutect2, varscan2
- MUC4 | c.14951C>T p.T4984M (on ENST00000463781 / NM_018406.7; = p.T748M on NM_004532.6) | Missense Mutation (SNP) | VAF 62/553 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs369127921; called by muse, mutect2, varscan2
- MUC5B | c.6893C>A p.P2298H | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV101500889, COSV71590937; called by muse, mutect2
- MUC5B | c.15497C>T p.P5166L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.165); catalogued as rs764462339, COSV71590947; called by muse, mutect2, varscan2
- MUTYH | c.974A>G p.D325G | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV58343820; called by muse, mutect2
- MVB12B | c.379T>C p.F127L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV63257732; called by muse, mutect2, varscan2
- MYB | c.806T>C p.I269T | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs778761961, COSV57197063; called by muse, mutect2, varscan2
- MYH14 | c.4993C>T p.R1665C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs764344864, COSV51813361; called by muse, mutect2, varscan2
- MYH9 | c.5489G>A p.R1830H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as rs966415372, COSV53383875; called by muse, mutect2
- MYL1 | c.131A>C p.K44T | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.093); catalogued as COSV61681421; called by muse, varscan2
- MYO10 | c.5537C>T p.A1846V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs899739570, COSV57019095; called by muse, mutect2, varscan2
- MYO1F | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs766761177, COSV57793133; called by muse, mutect2
- MYOF | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs771328774, COSV63701969; called by muse, mutect2, varscan2
- MYORG | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV52626231; called by muse, mutect2, varscan2
- NAA50 | c.341A>C p.Q114P | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53786152; called by muse, mutect2, varscan2
- NACA | c.381G>A p.K127= | Splice Region (SNP) | VAF 12/158 reads (8%) | catalogued as COSV63268762; called by muse, mutect2
- NBEAL1 | c.6226A>G p.M2076V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369250611; called by muse, mutect2, varscan2
- NBPF11 | c.1723T>G p.L575V | Missense Mutation (SNP) | VAF 30/596 reads (5%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.874); catalogued as rs1361522028; called by muse, mutect2
- NCAN | c.3875A>G p.Q1292R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs775943135, COSV53048609; called by muse, mutect2, varscan2
- NCK2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs763482146, COSV51888887; called by muse, mutect2, varscan2
- NCOR1 | c.6190G>A p.A2064T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV51968230; called by muse, varscan2
- NDOR1 | c.858del p.T287Rfs*105 | Frame Shift Del (DEL) | VAF 30/186 reads (16%) | catalogued as rs769937611; called by mutect2, pindel, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs747914168; called by mutect2, varscan2
- NDUFV1 | c.428T>G p.L143R | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV59595005; called by muse, varscan2
- NEPRO | c.1615A>G p.T539A | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1459248933, COSV55606219; called by muse, mutect2
- NFX1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV59309208; called by muse, mutect2, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | catalogued as rs111948120; called by mutect2, pindel, varscan2
- NIPBL | c.2035T>A p.S679T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs762097133, COSV56947116; called by muse, mutect2, varscan2
- NKAPD1 | c.479dup p.Q161Afs*26 (on ENST00000280352 / NM_001082970.2; = p.Q162Afs*26 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | catalogued as rs902183545; called by mutect2, varscan2
- NLRC5 | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 27/113 reads (24%) | catalogued as COSV52651987; called by muse, mutect2, varscan2
- NLRP3 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60221810; called by muse, mutect2, varscan2
- NMT2 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65381841; called by muse, mutect2, varscan2
- NOB1 | c.1138A>G p.S380G | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52061146; called by muse, mutect2, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOL6 | c.1963G>T p.G655C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53040408; called by muse, mutect2, varscan2
- NOL9 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV66625595; called by muse, mutect2, varscan2
- NOP14 | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV58624586; called by muse, mutect2
- NOTCH1 | c.5939T>C p.L1980P | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53039072; called by muse, mutect2
- NOTCH1 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); catalogued as rs752071569, COSV53039096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH4 | c.4475G>A p.R1492Q | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs761314959, COSV66679639; called by muse, mutect2, varscan2
- NPBWR2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs370307704; called by muse, mutect2, varscan2
- NPR2 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1285934866, COSV61309895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPRL2 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372473567; called by muse, mutect2, varscan2
- NR1I2 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0.011); catalogued as COSV61977808; called by muse, mutect2, varscan2
- NR3C2 | c.1468C>A p.P490T | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV60987559; called by muse, mutect2
- NR3C2 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as COSV60987567; called by muse, mutect2
- NR4A2 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954886860, COSV100277425, COSV59893212, COSV59894530; called by muse, mutect2, varscan2
- NRSN1 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV65893783, COSV65894029; called by muse, mutect2
- NRXN1 | c.4067C>T p.A1356V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV60490237; called by muse, mutect2
- NRXN1 | c.3366T>C p.P1122= | Splice Region (SNP) | VAF 18/83 reads (22%) | catalogued as rs1453751447, COSV58443061; called by muse, mutect2, varscan2
- NRXN3 | c.1640G>A p.R547Q (on ENST00000557594 / NM_001272020.2; = p.R971Q on NM_004796.6) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.34); catalogued as rs768341004, COSV55312468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSD1 | c.6430G>A p.A2144T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs761103348, COSV61773460, COSV99053189; called by mutect2, varscan2
- NSD2 | c.3394C>A p.P1132T | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56388618; called by muse, mutect2
- NTMT1 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV52964662; called by muse, mutect2
- NTRK1 | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62324479; called by muse, mutect2
- NUDT14 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100242006; called by muse, mutect2
- NUTM2G | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.209); catalogued as rs374944512; called by muse, mutect2, varscan2
- NYNRIN | c.1311del p.L438Wfs*31 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs1427934210; called by mutect2, varscan2
- OBP2A | c.161T>G p.V54G | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59791371; called by muse, mutect2, varscan2
- OBSCN | c.4233G>T p.Q1411H | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.594); catalogued as COSV52756294; called by muse, mutect2
- OCLN | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); catalogued as rs765029327, COSV62285089; called by muse, mutect2
- OGFRL1 | c.490del p.L164* | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as COSV100965759; called by mutect2, pindel
- OPRK1 | c.1109T>C p.L370P | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV55569214; called by muse, mutect2
- OR11L1 | c.636del p.L213* | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | catalogued as rs765635602; called by mutect2, pindel, varscan2
- OR13C5 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66164432; called by muse, mutect2, varscan2
- OR1D5 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV73859496; called by muse, mutect2
- OR2L3 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as COSV100741989, COSV63454825; called by muse, mutect2, varscan2
- OR4C15 | c.251T>C p.L84S (on ENST00000314644; = p.L30S on NM_001001920.2) | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.444); catalogued as COSV58951819; called by muse, mutect2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as rs755413956; called by mutect2, varscan2
- OR51I1 | c.99C>A p.F33L | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100971190, COSV66507555, COSV66509218; called by muse, mutect2, varscan2
- OR51S1 | c.420C>G p.Y140* | Nonsense Mutation (SNP) | VAF 14/137 reads (10%) | catalogued as COSV59057847; called by muse, mutect2
- OR52R1 | c.356T>C p.M119T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.663); catalogued as rs982601332, COSV61887897; called by muse, mutect2, varscan2
- OR5AR1 | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57252729, COSV57253281; called by muse, mutect2, varscan2
- OSM | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as COSV53161014; called by muse, mutect2, varscan2
- OSTM1 | c.989A>G p.Q330R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV51969619; called by mutect2, varscan2
- OXCT2 | c.767del p.P256Qfs*11 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | catalogued as rs756942160; called by mutect2, pindel
- OXR1 | c.1616G>A p.G539E (on ENST00000442977 / NM_001198532.1; = p.G538E on NM_018002.3) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.348); catalogued as COSV56326310; called by muse, mutect2, varscan2
- P2RY14 | c.227T>C p.F76S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56373280; called by muse, mutect2, varscan2
- P4HB | c.1359G>A p.T453= | Splice Region (SNP) | VAF 13/37 reads (35%) | catalogued as rs1303523010, COSV58940517; called by muse, mutect2, varscan2
- PAGE2 | c.117A>C p.E39D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.415); catalogued as COSV66595928; called by mutect2, varscan2
- PAN2 | c.2652C>T p.G884= (on ENST00000425394 / NM_001127460.3; = p.G880= on NM_014871.5) | Splice Region (SNP) | VAF 15/81 reads (19%) | catalogued as rs767055164, COSV57753204; called by muse, mutect2, varscan2
- PAN2 | c.1727A>G p.Q576R | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57753210; called by muse, mutect2
- PAPSS2 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs766402310, COSV63262950; called by muse, mutect2, varscan2
- PARD3B | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as rs766875287, COSV100593350, COSV62506538; called by muse, mutect2, varscan2
- PAX6 | c.1124dup p.H376Tfs*36 | Frame Shift Ins (INS) | VAF 16/67 reads (24%) | catalogued as rs756801119; called by mutect2, varscan2
- PAX9 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV64061355; called by muse, mutect2, varscan2
- PCARE | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1335218394, COSV59053908; called by muse, mutect2
- PCDH17 | c.2114C>T p.S705L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV64972953; called by muse, mutect2, varscan2
- PCDH19 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867012022, COSV55259918; called by muse, mutect2, varscan2
- PCDHA13 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as rs1436655611, COSV56487931; called by muse, mutect2
- PCDHA13 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1313975286, COSV56487940; called by muse, mutect2, varscan2
- PCDHA3 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV63540073; called by muse, mutect2
- PCDHA8 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs111750019, COSV65324727; called by muse, mutect2, varscan2
- PCDHB12 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs782365765, COSV53394584, COSV53400433; called by muse, mutect2, varscan2
- PCDHB14 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53387522; called by muse, mutect2
- PCDHB5 | c.2381T>C p.L794S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs367972692, COSV50648689; called by muse, mutect2
- PCDHB8 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 70/734 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.02); catalogued as rs1348378409, COSV50753687; called by muse, mutect2
- PCDHGA4 | c.2426C>T p.T809M | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); catalogued as rs1163396034, COSV53919324; called by muse, mutect2, varscan2
- PCDHGB4 | c.1913A>C p.Q638P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53919336; called by mutect2, varscan2
- PCDHGB5 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs770516092, COSV53919345; called by muse, mutect2, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 60/200 reads (30%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCED1B | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV71395029; called by muse, mutect2, varscan2
- PCNT | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs753157321, COSV64026589; called by muse, mutect2, varscan2
- PCNT | c.3166G>T p.G1056C | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV64026594; called by muse, mutect2, varscan2
- PDE10A | c.631A>T p.I211F | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV63093730; called by muse, mutect2
- PDE12 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV60818324; called by muse, mutect2, varscan2
- PDE8A | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.272); catalogued as COSV59635748; called by muse, mutect2, varscan2
- PDGFA | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601541, COSV63279373; called by muse, mutect2
- PDZRN3 | c.1004T>C p.V335A | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55194499; called by muse, mutect2, varscan2
- PEX16 | c.462T>C p.D154= | Splice Region (SNP) | VAF 28/121 reads (23%) | catalogued as rs1406562067, COSV53801311; called by muse, mutect2, varscan2
- PGK1 | c.1226C>A p.P409H | Missense Mutation (SNP) | VAF 50/498 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59371030; called by muse, mutect2
- PHACTR2 | c.685dup p.T229Nfs*5 | Frame Shift Ins (INS) | VAF 20/74 reads (27%) | catalogued as rs746858891; called by mutect2, varscan2
- PHF8 | c.553C>T p.H185Y (on ENST00000357988 / NM_001184896.1; = p.H149Y on NM_015107.3) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV57679088; called by muse, mutect2, varscan2
- PHYKPL | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV57423428; called by muse, mutect2, varscan2
- PIP4K2A | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV60540389; called by muse, mutect2
- PIP5KL1 | c.668G>A p.C223Y (on ENST00000388747 / NM_001135219.2; = p.C20Y on NM_173492.1) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55944324; called by muse, mutect2, varscan2
- PKDREJ | c.2111dup p.L704Ffs*16 | Frame Shift Ins (INS) | VAF 11/83 reads (13%) | catalogued as rs764753288; called by mutect2, pindel, varscan2
- PKHD1 | c.6325C>A p.P2109T | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61867097; called by muse, mutect2
- PLA2G3 | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV53208508; called by muse, mutect2, varscan2
- PLEC | c.11009A>G p.D3670G (on ENST00000322810 / NM_201380.4; = p.D3560G on NM_000445.5) | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV59617390; called by muse, mutect2, varscan2
- PLEC | c.8902C>T p.R2968W (on ENST00000322810 / NM_201380.4; = p.R2858W on NM_000445.5) | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs781797258, COSV59603936; called by muse, varscan2
- PLEKHG2 | c.2215del p.V739Yfs*51 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | catalogued as COSV52687491; called by mutect2, pindel
- PNLIPRP3 | c.152A>C p.K51T | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV100982644, COSV65047421; called by muse, mutect2, varscan2
- POLD1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV70954639; called by muse, mutect2
- POLN | c.2338A>G p.M780V | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV67024239; called by muse, mutect2
- POLR1B | c.2782A>G p.M928V | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54496426; called by muse, mutect2
- POLR2E | c.12G>C p.E4D | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs1168315618, COSV53123678, COSV53123859; called by muse, mutect2
- POMGNT2 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.988); catalogued as rs371405205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPFIA2 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs373118660; called by mutect2, varscan2
- PPFIA3 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV61950581; called by muse, mutect2, varscan2
- PPFIBP2 | c.160A>G p.I54V | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55075590; called by muse, mutect2, varscan2
- PPM1B | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56764965, COSV56765756; called by muse, mutect2, varscan2
- PPP3CA | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 7/103 reads (7%) | catalogued as COSV59921283; called by muse, mutect2
- PPP6C | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as rs144776498; called by muse, mutect2, varscan2
- PRDM16 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV54585290; called by muse, mutect2, varscan2
- PRICKLE2 | c.866G>A p.R289H (on ENST00000295902; = p.R233H on NM_198859.4) | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55764575; called by muse, mutect2
- PRKCI | c.826del p.T276Qfs*7 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs753143066; called by mutect2, varscan2
- PRKD3 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs750199145, COSV52211706; called by muse, mutect2, varscan2
- PRKX | c.599+2T>C p.X200_splice | Splice Site (SNP) | VAF 14/142 reads (10%) | catalogued as rs1305797726, COSV53322895; called by muse, mutect2, varscan2
- PRPSAP2 | c.1075T>C p.S359P | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52065157, COSV99264472; called by muse, mutect2, varscan2
- PRRC2C | c.785_787del p.P262del (on ENST00000367742; = p.P260del on NM_015172.4) | In Frame Del (DEL) | VAF 13/100 reads (13%) | catalogued as rs769533173; called by pindel, varscan2
- PRSS57 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs372754995; called by muse, mutect2, varscan2
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as COSV99194092; called by mutect2, pindel, varscan2
- PSG1 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 98/371 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs766886374, COSV54946665; called by muse, mutect2, varscan2
- PSMA3 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as rs750651588, COSV53616721; called by muse, mutect2, varscan2
- PSMG3 | c.337A>G p.R113G | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV52920520; called by muse, mutect2, varscan2
- PTCD1 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs199936067, COSV52862258, COSV99463956; called by mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | catalogued as rs778292578; called by mutect2, varscan2
- PTPN22 | c.1325T>C p.V442A (on ENST00000359785 / NM_001193431.2; = p.V387A on NM_012411.5) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63084596; called by muse, mutect2, varscan2
- PTPN9 | c.1294A>G p.T432A | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as COSV60723121; called by muse, mutect2, varscan2
- PTPRN2 | c.2711C>T p.T904M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66104701; called by muse, mutect2, varscan2
- PWWP2B | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs369979581; called by muse, mutect2, varscan2
- PXDC1 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV66665868; called by muse, mutect2, varscan2
- QSOX1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs747164407, COSV62580047; called by muse, mutect2, varscan2
- R3HDM4 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1167668216, COSV64292902; called by muse, mutect2, varscan2
- RAB22A | c.198A>G p.R66= | Splice Region (SNP) | VAF 5/24 reads (21%) | catalogued as COSV54830803; called by muse, mutect2, varscan2
- RAB2B | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52968111; called by muse, mutect2, varscan2
- RAB39B | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs782719018, COSV65624392; called by muse, mutect2, varscan2
- RABGAP1 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as rs1482227640, COSV58059924; called by muse, mutect2, varscan2
- RAD51AP2 | c.2595dup p.P866Sfs*4 | Frame Shift Ins (INS) | VAF 5/13 reads (38%) | catalogued as rs767724258; called by mutect2, varscan2
- RAD54B | c.699A>C p.K233N | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV60250402; called by muse, mutect2
- RAD54L2 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV56577774; called by muse, mutect2, varscan2
- RAG1 | c.982T>C p.C328R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55024423, COSV55029105; called by muse, mutect2, varscan2
- RAI1 | c.2290G>T p.E764* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as COSV55391355; called by muse, mutect2, varscan2
- RALGAPA1 | c.3106+2C>T p.X1036_splice | Splice Site (SNP) | VAF 23/86 reads (27%) | catalogued as rs1239768071, COSV51879363; called by muse, mutect2, varscan2
- RASAL1 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs531834126, COSV55654427; called by muse, mutect2, varscan2
- RBL2 | c.3361A>C p.N1121H | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV50874297; called by muse, mutect2, varscan2
- RBM12B | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as rs17853904, COSV67897628; called by muse, mutect2, varscan2
- RBM27 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs540414884, COSV54588605; called by muse, mutect2, varscan2
- RBM39 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53614519; called by muse, mutect2
- RBM47 | c.1673A>G p.N558S (on ENST00000295971 / NM_001098634.2; = p.N489S on NM_019027.4) | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1470603849, COSV55932262; called by muse, mutect2
- RBSN | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1490076194, COSV53792053; called by muse, mutect2, varscan2
- RCSD1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.321); catalogued as COSV63258418; called by muse, mutect2
- RERE | c.2897del p.P966Lfs*4 | Frame Shift Del (DEL) | VAF 42/179 reads (23%) | catalogued as rs5772316; called by mutect2, pindel, varscan2
- RFNG | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs755199513, COSV57648189; called by muse, mutect2, varscan2
- RFX2 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV57940395; called by muse, mutect2, varscan2
- RNASE9 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58880175; called by muse, mutect2
- RNF144A | c.604A>G p.M202V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV57981439; called by muse, mutect2, varscan2
- RNF213 | c.1792G>A p.V598M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60630462; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 29/185 reads (16%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO2 | c.3091A>T p.M1031L | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV59903456; called by muse, mutect2
- RPIA | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as rs886056422, COSV52168712; ClinVar: uncertain significance; called by muse, mutect2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL28 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as rs755058781, COSV59804529; called by mutect2, varscan2
- RPLP2 | c.295_297del p.K99del | In Frame Del (DEL) | VAF 23/64 reads (36%) | catalogued as rs777924285; called by pindel, varscan2
- RRS1 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52554124; called by muse, mutect2
- RS1 | c.629T>G p.I210S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs757697856, COSV66106062; called by muse, mutect2, varscan2
- RSKR | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs780596652, COSV56381469; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs759252078; called by mutect2, varscan2
- RTL9 | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 31/420 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71825462; called by muse, mutect2
- RUFY1 | c.745G>T p.G249W | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60159039; called by muse, mutect2, varscan2
- RXFP4 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as COSV58142760; called by muse, mutect2, varscan2
- RYR2 | c.5695C>T p.P1899S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV63674487; called by muse, mutect2, varscan2
- RYR3 | c.11399A>T p.N3800I (on ENST00000389232; = p.N3801I on NM_001036.6) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66782666; called by muse, mutect2, varscan2
- S1PR1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs140298731; called by muse, mutect2, varscan2
- SALL3 | c.2759C>T p.P920L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs781771204, COSV73305892, COSV73306233; called by muse, varscan2
- SARDH | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1366811300, COSV53832611, COSV53833571; called by muse, mutect2, varscan2
- SCARF1 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs780488988, COSV53957358; called by muse, varscan2
738 further variants in this file (378 protein-altering or splice-affecting, 334 silent, 26 other) are not listed here.
